Somatic mutation profile of tumor specimen TCGA-HU-A4H8-01A (aliquot TCGA-HU-A4H8-01A-11D-A25D-08) from TCGA case TCGA-HU-A4H8, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.5 years (28,292 days).
Specimen TCGA-HU-A4H8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 676778fa-5f2b-4467-9ad4-1de38350c569.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4H8-10A (Blood Derived Normal), aliquot TCGA-HU-A4H8-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86c33ce6-2ab5-4257-8c31-bbbca1029439

The open-access MAF lists 1,395 somatic variants for this specimen: 1,045 protein-altering or splice-affecting, 319 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 707, Silent 319, Frame Shift Del 224, Frame Shift Ins 47, Nonsense Mutation 29, Splice Site 16, In Frame Del 13, Intron 12, RNA 9, Splice Region 7, 3'UTR 5, 5'UTR 3.

Variants (750 of 1,395; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CEP290 | c.6869del p.N2290Ifs*11 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs587783017, CD075343; ClinVar: pathogenic; called by mutect2, varscan2
- COL3A1 | c.4254G>A p.T1418= | Splice Region (SNP) | VAF 27/111 reads (24%) | catalogued as rs587779565, CS1412749, COSV58582634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 55/166 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs993665271, COSV57247611; called by muse, mutect2, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- KIF5A | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs121434444, CM060295, COSV54051972; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MEN1 | c.1561del p.R521Gfs*43 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs767319284, CD972318, CM080439, COSV53644931; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 25/96 reads (26%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- NDE1 | c.733del p.L245Sfs*26 (on ENST00000577101; = p.L245Sfs*113 on NM_017668.3) | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs749768828; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PKD2 | c.2159del p.N720Ifs*17 | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | catalogued as rs757757289; ClinVar: pathogenic; called by mutect2, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 52/110 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB8 | c.1709G>A p.R570H (on ENST00000297504 / NM_001282291.2; = p.R553H on NM_007188.5) | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52502519; called by muse, mutect2, varscan2
- ABCC5 | c.506G>T p.R169M | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV55587533; called by muse, mutect2, varscan2
- ABCG1 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302262582, COSV59200688, COSV59207718; called by muse, mutect2, varscan2
- ABHD2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as rs778316032, COSV61772980; called by muse, mutect2, varscan2
- ABR | c.512G>A p.G171D (on ENST00000302538 / NM_021962.5; = p.G134D on NM_001092.5) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52142122; called by muse, mutect2, varscan2
- AC004593.2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs950872576, COSV56087851; called by muse, mutect2, varscan2
- AC092143.1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs941774548, COSV59247158; called by muse, mutect2, varscan2
- ACACB | c.7199G>A p.R2400H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs368161191; called by muse, mutect2, varscan2
- ACIN1 | c.3359del p.P1120Hfs*110 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs756288275; called by mutect2, pindel
- ACOT8 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746146702, COSV54168520; called by muse, mutect2, varscan2
- ACOT8 | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as rs758520030, COSV54168533; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 56/82 reads (68%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ACVR2B | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as rs761653104, COSV61701328; called by muse, mutect2, varscan2
- ADAM9 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs766583766, COSV65958886; called by muse, mutect2, varscan2
- ADAMTS1 | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as rs1204150067, COSV53168846; called by muse, mutect2, varscan2
- ADAMTS10 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs147270233, COSV54356260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS14 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528519283, COSV64599875; called by muse, mutect2, varscan2
- ADAMTS16 | c.2917C>T p.P973S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.48); catalogued as rs1169100392, COSV56979827; called by muse, mutect2, varscan2
- ADAMTS5 | c.1567C>T p.R523C | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs759375195, COSV53176118; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54996813; called by muse, mutect2, varscan2
- ADGRB1 | c.4426C>T p.R1476W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778880062, COSV60092020; called by muse, mutect2, varscan2
- ADGRD1 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV55439743, COSV55456566; called by muse, mutect2, varscan2
- ADGRL3 | c.1090C>T p.R364W (on ENST00000506720 / NM_001322402.2; = p.R296W on NM_015236.6) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747620859, COSV72266187, COSV72269826; called by muse, mutect2, varscan2
- ADRA2B | c.188C>T p.T63M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV69787229; called by muse, mutect2
- AFDN | c.4936G>A p.A1646T (on ENST00000447894 / NM_001366320.1; = p.A1644T on NM_001040000.3) | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.953); catalogued as rs150601242, COSV60038422; called by muse, mutect2, varscan2
- AFF2 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV53978240; called by muse, mutect2, varscan2
- AHCTF1 | c.3885del p.K1295Nfs*11 (on ENST00000366508; = p.K1269Nfs*11 on NM_015446.5) | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as COSV58251593; called by mutect2, pindel, varscan2
- AHNAK2 | c.9293C>T p.T3098M | Missense Mutation (SNP) | VAF 86/292 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs374657511, COSV60907227; called by muse, mutect2, varscan2
- AICDA | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs141451637, COSV57563578; called by muse, mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | catalogued as rs757477831; called by mutect2, pindel, varscan2
- AKAP9 | c.10322G>A p.R3441H (on ENST00000359028; = p.R3417H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as rs770556341, COSV62337987; called by muse, mutect2, varscan2
- ALG10B | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549039230, COSV100440002; called by muse, mutect2, varscan2
- ALOX12B | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772232919, COSV59871253; called by muse, varscan2
- ALOX12B | c.1799G>A p.R600Q | Missense Mutation (SNP) | VAF 124/338 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.136); catalogued as rs1333287390, COSV59871261; called by muse, varscan2
- ALPK2 | c.1067del p.L356Yfs*2 | Frame Shift Del (DEL) | VAF 34/108 reads (31%) | catalogued as rs756508755; called by mutect2, pindel, varscan2
- ALPP | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67395719; called by muse, mutect2, varscan2
- AMBP | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV54322445; called by muse, mutect2
- ANGPT4 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs557880338, COSV67920719; called by muse, mutect2, varscan2
- ANK1 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV55873989; called by muse, varscan2
- ANKRD11 | c.4534C>T p.R1512C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.197); catalogued as rs372367879; called by muse, mutect2, varscan2
- ANKRD17 | c.6497G>A p.C2166Y | Missense Mutation (SNP) | VAF 82/236 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV58215992; called by muse, mutect2, varscan2
- ANKRD17 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV58216005; called by muse, mutect2, varscan2
- ANKRD42 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52614573; called by muse, mutect2, varscan2
- AOC2 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs760916686, COSV53824397; called by muse, mutect2, varscan2
- AP002512.3 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV54405679; called by muse, mutect2, varscan2
- AP4B1 | c.725G>T p.S242I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV56723508; called by muse, mutect2, varscan2
- AP4E1 | c.2988A>C p.K996N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.129); catalogued as COSV55915276; called by muse, mutect2, varscan2
- ARAP2 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs758152417, COSV58283066; called by muse, mutect2, varscan2
- ARFGEF3 | c.5944G>A p.G1982S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1395905825, COSV52450928, COSV52467455; called by muse, mutect2, varscan2
- ARHGAP27 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99299055; called by muse, varscan2
- ARHGAP45 | c.2486T>C p.I829T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57429631; called by muse, mutect2, varscan2
- ARHGEF11 | c.1429A>G p.N477D | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.414); catalogued as rs768881890, COSV63810575; called by muse, mutect2, varscan2
- ARID1A | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61372504; called by muse, mutect2, varscan2
- ARID3B | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.037); catalogued as COSV100654742; called by muse, mutect2, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | catalogued as rs1247324796; called by mutect2, varscan2
- ARMC7 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs758398697, COSV55460419; called by muse, mutect2, varscan2
- ASAH1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50501374; called by muse, mutect2
- ASAH2 | c.148del p.S50Qfs*40 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs772181094; called by mutect2, varscan2
- ASCC2 | c.291T>G p.Y97* | Nonsense Mutation (SNP) | VAF 51/127 reads (40%) | catalogued as COSV57072176; called by muse, mutect2, varscan2
- ASCC3 | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs747570359; called by mutect2, varscan2
- ASTE1 | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.146); catalogued as COSV53907713; called by muse, mutect2, varscan2
- ATE1 | c.1088T>A p.V363E | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56433748; called by muse, mutect2, varscan2
- ATE1 | c.289del p.M97Cfs*2 | Frame Shift Del (DEL) | VAF 12/41 reads (29%) | catalogued as COSV56433777; called by mutect2, pindel, varscan2
- ATG4C | c.958G>A p.V320M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs776125932, COSV58603935; called by muse, mutect2, varscan2
- ATP10D | c.1848dup p.L617Vfs*4 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs764067652; called by mutect2, varscan2
- ATP1A4 | c.2040G>C p.Q680H | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63625599, COSV63627933; called by muse, mutect2
- ATP6V0B | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV52542592; called by muse, mutect2, varscan2
- ATP7A | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV58443188; called by muse, mutect2, varscan2
- AURKAIP1 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs149654038; called by muse, mutect2, varscan2
- AZIN2 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53855965; called by muse, mutect2, varscan2
- BANP | c.1066G>A p.A356T (on ENST00000286122; = p.A325T on NM_017869.4) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1413298198, COSV53734069; called by muse, mutect2, varscan2
- BCKDHB | c.612del p.F204Lfs*26 | Frame Shift Del (DEL) | VAF 23/98 reads (23%) | catalogued as rs1210649507; called by mutect2, pindel, varscan2
- BIN1 | c.1461+1G>A p.X487_splice (on ENST00000316724 / NM_001320642.1; = p.X348_splice on NM_004305.4) | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as rs764951306, COSV52116089; called by muse, mutect2, varscan2
- BIN1 | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV52116102; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.79); catalogued as COSV57278520; called by muse, mutect2, varscan2
- BLMH | c.313del p.W105Gfs*11 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as COSV55587541; called by mutect2, pindel
- BOC | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.073); catalogued as rs141457641; called by muse, mutect2, varscan2
- BPIFB2 | c.575T>G p.I192S | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV50063203; called by muse, mutect2, varscan2
- BRD3 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57701704; called by muse, mutect2, varscan2
- BSN | c.7666C>T p.R2556W | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV56513509; called by muse, mutect2, varscan2
- BTN2A2 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV61856682; called by muse, mutect2, varscan2
- BUB3 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs868481483, COSV60592443; called by muse, mutect2, varscan2
- BZW1 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.432); catalogued as COSV100729885; called by muse, mutect2, varscan2
- C14orf93 | c.1049C>T p.T350I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs1381645271, COSV54440391; called by muse, mutect2, varscan2
- C16orf70 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs776164057, COSV54625726; called by muse, mutect2, varscan2
- C19orf12 | c.437C>T p.A146V (on ENST00000392278 / NM_001031726.3; = p.A135V on NM_031448.6) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV60364185; called by muse, varscan2
- C2CD3 | c.2735A>G p.D912G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58089978; called by muse, mutect2, varscan2
- C3orf22 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs771275774, COSV59072481, COSV59073563; called by muse, mutect2, varscan2
- C8orf74 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV58753569; called by muse, mutect2, varscan2
- CA8 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as COSV58770609; called by muse, mutect2, varscan2
- CACNA1A | c.4586G>T p.S1529I | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64190779; called by muse, mutect2, varscan2
- CACNA1A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV64190796; called by muse, mutect2, varscan2
- CACNA1B | c.1040T>C p.M347T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53115392; called by muse, mutect2, varscan2
- CACNA1S | c.4743G>T p.E1581D | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.061); catalogued as COSV62936638; called by muse, mutect2, varscan2
- CACNB2 | c.274C>T p.R92W (on ENST00000324631 / NM_201596.3; = p.R37W on NM_000724.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1441594267, COSV56613447, COSV56648679; called by muse, mutect2, varscan2
- CAD | c.4955G>A p.R1652H | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as rs745334945, COSV53024044; called by muse, mutect2, varscan2
- CAMK1G | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs200585732, COSV50520349; called by muse, mutect2, varscan2
- CAMTA1 | c.1574C>T p.T525I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV57883637; called by muse, mutect2
- CAMTA2 | c.2023G>T p.G675C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV61833332; called by muse, mutect2, varscan2
- CANX | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV56002786; called by muse, mutect2, varscan2
- CAP1 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV61222866; called by muse, mutect2, varscan2
- CAPN1 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54196873; called by muse, mutect2, varscan2
- CAPN5 | c.1211C>T p.T404M (on ENST00000456580; = p.T364M on NM_004055.5) | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs369083073; called by muse, mutect2, varscan2
- CARD10 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs1470982641, COSV52654591; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs770159446; called by mutect2, varscan2
- CASP8AP2 | c.3390del p.K1130Nfs*6 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs768812342; called by mutect2, varscan2
- CASZ1 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201167368; called by muse, mutect2, varscan2
- CCDC136 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756674345, COSV52796597; called by muse, mutect2, varscan2
- CCDC173 | c.197C>A p.T66K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV101352360, COSV69572556; called by muse, mutect2, varscan2
- CCDC3 | c.798dup p.Y267Lfs*25 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | catalogued as rs750606155; called by mutect2, varscan2
- CCDC38 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368457474; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC60 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.475); catalogued as rs771471436, COSV59540540; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC77 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV53472017; called by muse, mutect2, varscan2
- CCIN | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1007899869, COSV58724132; called by muse, mutect2, varscan2
- CCNB3 | c.2754G>C p.M918I | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV52070232; called by muse, mutect2, varscan2
- CCR1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV56121692; called by muse, mutect2, varscan2
- CD163L1 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs758979638, COSV58011752; called by muse, mutect2, varscan2
- CD164L2 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759199032, COSV64995489; called by muse, mutect2, varscan2
- CD248 | c.1949G>A p.G650D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV60935819, COSV60937595; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 39/117 reads (33%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD80 | c.95G>C p.C32S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.07); catalogued as COSV51801460; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs762805003; called by mutect2, varscan2
- CDC123 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.431); catalogued as rs199948914, COSV55396594; called by muse, mutect2, varscan2
- CDC42BPB | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs367791222; called by muse, mutect2, varscan2
- CDC45 | c.1597A>G p.T533A | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54243645; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 40/94 reads (43%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH18 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56904331; called by muse, mutect2, varscan2
- CDH5 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1335606003, COSV58515607; called by muse, mutect2, varscan2
- CDH5 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs768164275, COSV58516079; called by muse, mutect2, varscan2
- CDHR5 | c.1453C>G p.P485A (on ENST00000358353 / NM_001171968.2; = p.P491A on NM_021924.5) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV57641595, COSV57646682; called by muse, mutect2, varscan2
- CDK11A | c.1717C>T p.R573W (on ENST00000378633 / NM_001313896.2; = p.R570W on NM_024011.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs756189308, COSV52306871; called by muse, mutect2, varscan2
- CDKN2A | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs774633329, COSV58684967, COSV58691212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR2 | c.6557G>A p.R2186H | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs141644848; called by muse, mutect2, varscan2
- CELSR3 | c.3454C>T p.R1152W | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754395490, COSV50840851; called by muse, mutect2, varscan2
- CEP170 | c.4140C>G p.N1380K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV60506584; called by muse, mutect2, varscan2
- CEP350 | c.4874G>A p.R1625Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62599140; called by muse, mutect2, varscan2
- CFAP299 | c.448del p.R150Dfs*9 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs761800837; called by mutect2, varscan2
- CFAP45 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs770179632, COSV63648159; called by muse, mutect2, varscan2
- CFAP65 | c.1738C>T p.R580C | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs775369558, COSV58558422; called by muse, mutect2, varscan2
- CHD4 | c.5365C>T p.R1789C (on ENST00000357008 / NM_001363606.2; = p.R1800C on NM_001273.5) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1480327213, COSV58895619; called by muse, mutect2, varscan2
- CHD4 | c.4249C>T p.R1417* (on ENST00000357008 / NM_001363606.2; = p.R1430* on NM_001273.5) | Nonsense Mutation (SNP) | VAF 55/211 reads (26%) | catalogued as COSV58895634; called by muse, mutect2, varscan2
- CHRD | c.2200C>T p.R734* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as rs1177348589, COSV52605456; called by muse, mutect2, varscan2
- CILP | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs562122822, COSV56022222; called by muse, mutect2, varscan2
- CILP2 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs776481912, COSV52272812; called by muse, mutect2, varscan2
- CLASP1 | c.2477A>G p.D826G | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55315147; called by muse, mutect2, varscan2
- CLCA1 | c.2057G>A p.R686Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs199729425; called by muse, mutect2, varscan2
- CLCN3 | c.1062dup p.A355Cfs*17 | Frame Shift Ins (INS) | VAF 28/81 reads (35%) | catalogued as rs1188097023; called by mutect2, pindel, varscan2
- CLCN7 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); catalogued as COSV51968935; called by muse, mutect2, varscan2
- CMTM8 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs149787700; called by muse, mutect2, varscan2
- CNDP1 | c.332C>A p.P111H | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62593229; called by muse, mutect2, varscan2
- CNGB1 | c.2231G>T p.S744I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99210367; called by muse, mutect2
- CNGB3 | c.2091G>T p.E697D | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.395); catalogued as COSV60685326; called by muse, mutect2, varscan2
- CNRIP1 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV55147719; called by muse, mutect2, varscan2
- CNST | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs747334742, COSV63619847; called by muse, mutect2, varscan2
- CNTN2 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs200893856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTRL | c.5405del p.K1802Sfs*9 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | catalogued as rs1217756472; called by mutect2, pindel, varscan2
- COL1A1 | c.3770G>A p.R1257H | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775462973, COSV99867741; called by muse, mutect2, varscan2
- COL22A1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57361646; called by muse, mutect2, varscan2
- COL25A1 | c.1488del p.G497Efs*14 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | catalogued as COSV101211681; called by mutect2, pindel, varscan2
- COL25A1 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as rs773947674, COSV67646804; called by muse, mutect2, varscan2
- COL28A1 | c.1408G>T p.G470W | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68080764; called by muse, mutect2, varscan2
- COL4A3 | c.3086G>A p.R1029K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59257525; called by muse, mutect2, varscan2
- COL9A3 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs147134081; called by muse, mutect2, varscan2
- COX18 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV55719786; called by muse, mutect2, varscan2
- COX4I1 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as rs371834112; called by muse, varscan2
- COX7B | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs782609880, COSV64864503; called by muse, mutect2, varscan2
- CPAMD8 | c.2707C>T p.R903C (on ENST00000651564; = p.R856C on NM_015692.5) | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs369376971; called by muse, mutect2, varscan2
- CRAMP1 | c.2350C>T p.R784W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762190804, COSV51960010; called by muse, mutect2, varscan2
- CREM | c.778G>A p.A260T (on ENST00000429130; = p.A215T on NM_181571.3) | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59765449; called by muse, mutect2, varscan2
- CRISP1 | c.615A>C p.K205N | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as COSV59992863; called by muse, mutect2, varscan2
- CROT | c.102del p.K34Nfs*6 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs756999481; called by mutect2, pindel, varscan2
- CRTAM | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as rs775161741, COSV57066614; called by muse, mutect2, varscan2
- CRTC1 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58716715; called by muse, mutect2, varscan2
- CRYBB3 | c.470+1G>A p.X157_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as rs754250272, COSV53194144; called by muse, mutect2, varscan2
- CRYGA | c.476dup p.A160Cfs*29 | Frame Shift Ins (INS) | VAF 50/150 reads (33%) | catalogued as rs762650691; called by mutect2, varscan2
- CSF2RB | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1407645980, COSV53255811; called by muse, mutect2, varscan2
- CSK | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs754759286, COSV54972715; called by muse, mutect2, varscan2
- CSMD3 | c.8051A>C p.N2684T (on ENST00000297405 / NM_001363185.1; = p.N2580T on NM_052900.3) | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.487); catalogued as COSV52111492, COSV52195148; called by muse, mutect2, varscan2
- CST6 | c.241-1G>A p.X81_splice | Splice Site (SNP) | VAF 41/102 reads (40%) | catalogued as COSV56409133; called by muse, mutect2, varscan2
- CTNND2 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs373393242; called by muse, mutect2, varscan2
- CTTN | c.766T>A p.L256M | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as COSV57230417; called by muse, mutect2, varscan2
- CUX1 | c.1289dup p.P431Sfs*16 | Frame Shift Ins (INS) | VAF 27/101 reads (27%) | catalogued as rs782381199; called by mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 30/153 reads (20%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP2B6 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs368451099, COSV57842403; called by muse, mutect2, varscan2
- CYP4F2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs140630977; called by muse, mutect2, varscan2
- CYP4F3 | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55407435; called by muse, mutect2, varscan2
- DACH2 | c.1281G>C p.L427F | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV64162744; called by muse, mutect2, varscan2
- DAGLB | c.1675C>A p.L559I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51702515; called by muse, mutect2, varscan2
- DDX10 | c.238del p.T80Hfs*2 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs1176416201; called by mutect2, pindel, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs759023106; called by mutect2, varscan2
- DENND1A | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV65322853; called by muse, mutect2
- DENND3 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs1465503164, COSV52801052, COSV52807046; called by muse, mutect2, varscan2
- DGKA | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754616028, COSV59384379; called by muse, mutect2, varscan2
- DGKQ | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as rs147014854, COSV56616367; called by muse, mutect2, varscan2
- DHX38 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs763111684, COSV51696445; called by muse, mutect2, varscan2
- DHX40 | c.1894G>C p.A632P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52066212; called by muse, mutect2, varscan2
- DIO2 | c.56del p.F19Sfs*23 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | catalogued as rs148778534; called by mutect2, pindel, varscan2
- DIXDC1 | c.683G>A p.S228N (on ENST00000440460 / NM_001037954.4; = p.S17N on NM_033425.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as COSV59461210; called by muse, mutect2, varscan2
- DLGAP3 | c.2001-1G>A p.X667_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52391796; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF1 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1358496491; called by muse, mutect2
- DNAH1 | c.11357C>T p.P3786L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56231073; called by muse, mutect2, varscan2
- DNAH17 | c.9446C>T p.T3149I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs374825191; called by muse, mutect2, varscan2
- DNAH5 | c.2768A>G p.D923G | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54206500; called by muse, mutect2, varscan2
- DNAJB2 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs373229634, COSV60675890; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAJC18 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as rs1249640948, COSV57415125; called by muse, mutect2, varscan2
- DNAJC6 | c.726del p.F244Sfs*31 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as COSV54781712; called by mutect2, pindel, varscan2
- DNAJC6 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs1330522023, COSV54770382; called by muse, mutect2, varscan2
- DNMBP | c.4636A>G p.K1546E | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.129); catalogued as rs1054575908, COSV60621111; called by muse, mutect2
- DNMT3L | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV54263358; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 31/61 reads (51%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs756307668, COSV69854206; called by muse, mutect2, varscan2
- DOCK7 | c.5102G>A p.R1701Q (on ENST00000635253 / NM_001367561.1; = p.R1670Q on NM_033407.3) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs191312236, COSV51996863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOLK | c.685G>C p.V229L | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV58279991; called by muse, mutect2, varscan2
- DPF1 | c.467_469del p.K156del | In Frame Del (DEL) | VAF 54/151 reads (36%) | catalogued as rs753495424; called by pindel, varscan2
- DPF3 | c.682del p.D228Mfs*44 | Frame Shift Del (DEL) | VAF 48/175 reads (27%) | catalogued as COSV63500150; called by mutect2, pindel, varscan2
- DPP3 | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64756091; called by muse, mutect2, varscan2
- DPP4 | c.668dup p.L223Ffs*7 | Frame Shift Ins (INS) | VAF 21/71 reads (30%) | catalogued as rs1299375730; called by mutect2, pindel, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 48/193 reads (25%) | catalogued as rs1475611014; called by mutect2, varscan2
- DQX1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 47/204 reads (23%) | catalogued as rs774452490, COSV66352977, COSV66353194; called by muse, mutect2, varscan2
- DSCAM | c.4471C>T p.R1491C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); catalogued as rs199555820, COSV68028171; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs750962255; called by mutect2, varscan2
- DTD1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.152); catalogued as rs1485383895, COSV66278258; called by muse, mutect2, varscan2
- DYNC1H1 | c.9109G>A p.A3037T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs769817685, COSV64134688; called by muse, mutect2, varscan2
- DYNC1H1 | c.10837A>G p.S3613G | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64134691; called by muse, mutect2, varscan2
- DYRK2 | c.782G>A p.R261Q (on ENST00000344096 / NM_006482.3; = p.R188Q on NM_003583.4) | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs752139842, COSV59845405; called by muse, mutect2, varscan2
- DZIP3 | c.3608G>A p.R1203Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs367842769; called by muse, mutect2, varscan2
- E2F3 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60896100; called by muse, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- EDNRB | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 34/81 reads (42%) | catalogued as rs763338098, COSV100527076, COSV57518763; called by muse, mutect2, varscan2
- EFCAB5 | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190450097, COSV57926515; called by muse, mutect2, varscan2
- EGR3 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57833018; called by muse, mutect2, varscan2
- ELP2 | c.2237G>A p.C746Y | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.429); catalogued as rs779844979, COSV100627084; called by muse, mutect2, varscan2
- ENTPD5 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV58220804; called by muse, mutect2, varscan2
- EPHA2 | c.2411G>A p.G804D | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64452193; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 56/96 reads (58%) | catalogued as rs775950025; called by mutect2, varscan2
- EVI2B | c.593dup p.N198Kfs*4 | Frame Shift Ins (INS) | VAF 42/120 reads (35%) | catalogued as rs765136869, COSV58364207; called by mutect2, varscan2
- EVI5L | c.1980G>A p.M660I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs927392803; called by muse, mutect2
- EXOC3L2 | c.2240del p.P747Lfs*49 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs1261630384; called by mutect2, pindel, varscan2
- EXOC7 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as rs548920286, COSV58739586; called by muse, mutect2, varscan2
- EXOSC10 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV58663922; called by muse, mutect2, varscan2
- EZHIP | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1006910285, COSV57955307; called by muse, mutect2, varscan2
- F2RL3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs573374669, COSV50185193, COSV50185702; called by muse, mutect2, varscan2
- FAM13A | c.2563-1G>T p.X855_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | catalogued as COSV51997403, COSV52006425; called by muse, mutect2, varscan2
- FAM193A | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1240997532, COSV61191277; called by muse, mutect2, varscan2
- FAM199X | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs370616867, COSV55433260; called by muse, mutect2, varscan2
- FAM209A | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 53/197 reads (27%) | catalogued as COSV54765963; called by muse, mutect2, varscan2
- FAM47C | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.405); catalogued as COSV63723981; called by muse, mutect2
- FAM81B | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as rs370398727; called by muse, mutect2, varscan2
- FANCI | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV55523710; called by muse, mutect2, varscan2
- FARP1 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs778325187, COSV60330904; called by muse, varscan2
- FAT4 | c.9805A>G p.T3269A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV58673193; called by muse, mutect2, varscan2
- FBN2 | c.7659dup p.F2554Vfs*4 | Frame Shift Ins (INS) | VAF 28/80 reads (35%) | catalogued as rs748600284; called by mutect2, varscan2
- FBXL7 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs576303242, COSV61641769; called by muse, mutect2, varscan2
- FBXO30 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as COSV52790313; called by muse, mutect2, varscan2
- FCHSD2 | c.928C>T p.R310* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV60806938; called by mutect2, varscan2
- FFAR4 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs1454563281, COSV65178491; called by muse, mutect2, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs35667286; called by mutect2, pindel
- FHL5 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs1331026642, COSV58735428, COSV58738259; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs777980924; called by mutect2, varscan2
- FHOD3 | c.3025G>A p.D1009N (on ENST00000359247 / NM_001281739.3; = p.D1026N on NM_025135.5) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs554487359, COSV57165602, COSV99941725; called by muse, mutect2, varscan2
- FIGNL2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs1362052485, COSV73729206; called by muse, mutect2, varscan2
- FLT4 | c.2437C>A p.L813M | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56099761; called by muse, mutect2, varscan2
- FLT4 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.901); catalogued as rs753074837, COSV56099795; called by muse, mutect2, varscan2
- FMN2 | c.4648G>A p.A1550T | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1190050762, COSV60418764, COSV60431587; called by muse, mutect2, varscan2
- FMNL1 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs749913183, COSV58955384; called by muse, mutect2, varscan2
- FOCAD | c.2791del p.S931Afs*11 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs776730128; called by mutect2, pindel
- FOXM1 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 158/440 reads (36%) | catalogued as COSV61205332; called by muse, mutect2, varscan2
- FPR2 | c.547T>C p.W183R | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60672031; called by muse, mutect2, varscan2
- FREM1 | c.3254G>A p.S1085N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs778342348, COSV66518404; called by muse, mutect2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRMPD4 | c.2753A>G p.E918G | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66211710; called by muse, mutect2
- FRRS1 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as rs932403157, COSV54920643; called by muse, mutect2, varscan2
- FSTL4 | c.1690G>A p.V564M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372077621; called by muse, mutect2, varscan2
- FTCD | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV52423482, COSV52429074; called by muse, mutect2, varscan2
- FTMT | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs764511341, COSV58419434, COSV58419728; called by muse, mutect2, varscan2
- FYN | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57610211; called by muse, mutect2, varscan2
- FZD5 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV54942958; called by muse, mutect2, varscan2
- GABBR2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.758); catalogued as rs763374888, COSV52294366; called by muse, mutect2
- GABRD | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763019253, COSV66079957; called by muse, mutect2, varscan2
- GALNT3 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV101204980, COSV67061410; called by muse, mutect2, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 7/35 reads (20%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GALNT6 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs142431103, COSV62541992; called by muse, mutect2, varscan2
- GALR3 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV50763842; called by muse, mutect2, varscan2
- GAS7 | c.400G>A p.A134T (on ENST00000432992 / NM_201433.2; = p.A74T on NM_201432.2) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs1266349442, COSV60432198; called by muse, mutect2, varscan2
- GBX2 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs1481565243, COSV60444911; called by muse, mutect2
- GET3 | c.982dup p.A328Gfs*90 | Frame Shift Ins (INS) | VAF 27/111 reads (24%) | catalogued as rs763284415; called by mutect2, pindel, varscan2
- GFOD2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as rs778494433, COSV52057078; called by muse, mutect2, varscan2
- GLB1L | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 75/241 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as rs1044497532, COSV55475517; called by muse, mutect2, varscan2
- GLI2 | c.1598G>A p.R533H (on ENST00000361492 / NM_001374353.1; = p.R550H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229340491, COSV58035376; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 25/58 reads (43%) | catalogued as rs749150409; called by mutect2, varscan2
- GMPPB | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.046); catalogued as rs748809549, COSV57537655; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GMPR2 | c.1040C>T p.A347V (on ENST00000355299 / NM_001351022.2; = p.A365V on NM_016576.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs781312813, COSV57468169; called by muse, mutect2, varscan2
- GNB5 | c.1108G>A p.V370I (on ENST00000261837 / NM_016194.4; = p.V328I on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs763538889, COSV55897720; called by muse, mutect2, varscan2
- GOLGA3 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748744472, COSV52626115; called by muse, mutect2, varscan2
- GP2 | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as rs749963542, COSV56892246; called by muse, mutect2, varscan2
- GPATCH8 | c.4483C>T p.Q1495* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as COSV59193341; called by muse, mutect2, varscan2
- GPBP1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV53309937; called by muse, mutect2, varscan2
- GPC1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50862730; called by muse, mutect2, varscan2
- GPC5 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs559277707, COSV65579895; called by muse, varscan2
- GPHN | c.888G>T p.K296N (on ENST00000315266 / NM_001377519.1; = p.K329N on NM_020806.5) | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.775); catalogued as COSV59473758; called by muse, mutect2
- GPR137 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs1277508923, COSV57401165; called by muse, mutect2, varscan2
- GPR161 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs199866265, COSV54788031; called by muse, mutect2, varscan2
- GPR176 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV54443681; called by muse, mutect2, varscan2
- GPR182 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT tolerated (0.81); PolyPhen benign (0.027); catalogued as COSV55625568; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 40/115 reads (35%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR65 | c.371del p.F124Sfs*2 | Frame Shift Del (DEL) | VAF 54/166 reads (33%) | catalogued as rs770829884; called by mutect2, varscan2
- GPX2 | c.323A>C p.N108T | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63035979; called by muse, mutect2, varscan2
- GREB1 | c.375del p.S126Afs*50 | Frame Shift Del (DEL) | VAF 37/137 reads (27%) | catalogued as COSV52184662; called by mutect2, pindel, varscan2
- GRID2 | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.267); catalogued as COSV56177100; called by muse, mutect2, varscan2
- GRIK2 | c.951+1G>A p.X317_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV59714499; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN2A | c.3922T>C p.S1308P | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58022016; called by muse, mutect2, varscan2
- GRM2 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1488891900, COSV56583362; called by muse, mutect2, varscan2
- GRM4 | c.2621C>T p.T874M | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs146041340; called by muse, mutect2, varscan2
- GRM6 | c.2195C>T p.T732M | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs769306495, COSV51433893; called by muse, mutect2, varscan2
- GSDMB | c.408-1G>A p.X136_splice | Splice Site (SNP) | VAF 15/66 reads (23%) | catalogued as COSV58779746; called by muse, mutect2, varscan2
- GSN | c.1741-1G>T p.X581_splice | Splice Site (SNP) | VAF 11/41 reads (27%) | catalogued as COSV57994945; called by muse, mutect2, varscan2
- GYS1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1318179540, COSV54401478; called by muse, mutect2, varscan2
- H2BC21 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.894); catalogued as COSV58611335; called by muse, mutect2
- HADHB | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58544942; called by muse, mutect2, varscan2
- HARS2 | c.1258A>G p.N420D | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV51226813; called by muse, mutect2, varscan2
- HDAC1 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.124); catalogued as COSV65190540; called by muse, mutect2, varscan2
- HECW2 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.063); catalogued as rs767070217, COSV53650704; called by muse, mutect2, varscan2
- HEG1 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); catalogued as rs748790756, COSV60759713; called by muse, varscan2
- HEPHL1 | c.3401C>G p.S1134C | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.241); catalogued as rs1381533476, COSV100244267, COSV59889776, COSV59895075; called by muse, mutect2, varscan2
- HERC5 | c.2398A>G p.M800V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1305793096, COSV52037541; called by muse, mutect2, varscan2
- HESX1 | c.533del p.N178Ifs*10 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs759180706; called by mutect2, varscan2
- HIPK4 | c.1453C>T p.R485C | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.333); catalogued as rs759855803, COSV52519481; called by muse, mutect2, varscan2
- HIPK4 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs190827341; called by muse, mutect2, varscan2
- HIVEP1 | c.3041G>T p.R1014I | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65099040; called by muse, mutect2, varscan2
- HIVEP2 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50005975; called by muse, mutect2, varscan2
- HLA-E | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV64927257; called by muse, mutect2, varscan2
- HMBOX1 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 48/209 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs372399969; called by muse, mutect2, varscan2
- HMCN1 | c.3178G>A p.A1060T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.969); catalogued as rs149692259; called by muse, mutect2, varscan2
- HMCN1 | c.16030G>T p.G5344* | Nonsense Mutation (SNP) | VAF 77/227 reads (34%) | catalogued as COSV54880258; called by muse, mutect2, varscan2
- HMGCLL1 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748038716, COSV51441012; called by muse, mutect2, varscan2
- HNRNPL | c.1490A>G p.Q497R | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV55491241; called by muse, mutect2, varscan2
- HOXA5 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1352203462, COSV56072343, COSV56073848; called by muse, mutect2, varscan2
- HOXB5 | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs777962205, COSV53312162; called by muse, mutect2, varscan2
- HOXD13 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66832335; called by muse, mutect2, varscan2
- HOXD13 | c.951G>T p.E317D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV66832337; called by muse, mutect2, varscan2
- HS6ST1 | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV52126864; called by mutect2, varscan2
- HSDL1 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as rs766990002, COSV54740324; called by muse, mutect2, varscan2
- HSPA1A | c.1829T>G p.L610R | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100989457; called by muse, varscan2
- HSPA1B | c.1829T>G p.L610R | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100987926; called by muse, mutect2, varscan2
- HSPA6 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs763048231, COSV59060126; called by muse, mutect2, varscan2
- HSPG2 | c.8305A>G p.S2769G | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV65969247; called by muse, mutect2, varscan2
- HYAL2 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as rs1050074, COSV63305921; called by muse, mutect2, varscan2
- ICAM1 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV53423709; called by muse, mutect2, varscan2
- IGF2R | c.2905G>A p.V969I | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63626731; called by muse, mutect2, varscan2
- IGHMBP2 | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV54820329, COSV54822440; called by muse, mutect2, varscan2
- IGSF9B | c.3640G>A p.G1214S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); catalogued as rs1298295202, COSV58064324, COSV58073522; called by muse, mutect2, varscan2
- IL1RAPL1 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.907); catalogued as COSV56240404; called by muse, mutect2, varscan2
- IL23A | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs146998334; called by muse, mutect2, varscan2
- IL25 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as COSV59304822; called by muse, mutect2
- ILKAP | c.134C>A p.P45H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV54517493; called by muse, mutect2, varscan2
- IMP4 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.362); catalogued as rs777448885, COSV52091203; called by muse, mutect2, varscan2
- INTS1 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as rs544932870, COSV67176490; called by muse, mutect2, varscan2
- INTS3 | c.718C>T p.L240F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV59675408; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 14/18 reads (78%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IP6K1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); catalogued as rs757004314, COSV58662971; called by muse, mutect2, varscan2
- IPO9 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs768072057, COSV64232871; called by muse, mutect2, varscan2
- IQCF1 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs765230165, COSV58823090; called by muse, mutect2, varscan2
- IREB2 | c.1449del p.K483Nfs*60 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as COSV51923080; called by mutect2, pindel, varscan2
- ITGAD | c.1273del p.R425Afs*50 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs746237579, COSV66756833; called by mutect2, pindel, varscan2
- ITGB1BP2 | c.7_8del p.L3Tfs*4 | Frame Shift Del (DEL) | VAF 28/60 reads (47%) | catalogued as rs758495948; called by pindel, varscan2
- ITGB1BP2 | c.754-1G>A p.X252_splice | Splice Site (SNP) | VAF 10/14 reads (71%) | catalogued as COSV52135912; called by muse, mutect2, varscan2
- ITIH5 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV53660513; called by muse, mutect2, varscan2
- ITPR2 | c.7162G>A p.V2388I | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67265328; called by muse, mutect2, varscan2
- ITPR3 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200526442, COSV65406184; called by muse, mutect2, varscan2
- ITSN2 | c.5094G>T p.*1698Yext*3 | Nonstop Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100743154, COSV61944058; called by muse, mutect2, varscan2
- JAKMIP1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as COSV51523049; called by muse, mutect2, varscan2
- JCAD | c.2356G>A p.V786M | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.08); catalogued as COSV64758160; called by muse, mutect2, varscan2
- JPH1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 56/238 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs201314759, CM150143, COSV60608883; called by muse, mutect2, varscan2
- KALRN | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs987606026, COSV53753292; called by muse, mutect2, varscan2
- KALRN | c.5015C>T p.T1672M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375684753; called by muse, mutect2, varscan2
- KAZN | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65715179; called by muse, mutect2, varscan2
- KAZN | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65715184; called by muse, mutect2, varscan2
- KAZN | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.556); catalogued as rs763675136, COSV63206872; called by muse, mutect2, varscan2
- KBTBD2 | c.993A>C p.K331N | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.19); catalogued as COSV58362831; called by muse, mutect2, varscan2
- KBTBD4 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV55453822; called by muse, mutect2, varscan2
- KCNA10 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63904253; called by muse, mutect2, varscan2
- KCNC2 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV54363401, COSV54370119; called by muse, mutect2, varscan2
- KCNH5 | c.2890del p.Q964Rfs*59 | Frame Shift Del (DEL) | VAF 48/225 reads (21%) | catalogued as COSV59763617; called by mutect2, pindel, varscan2
- KCNJ6 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.079); catalogued as rs1315763642, COSV55710092; called by muse, mutect2, varscan2
- KCNN2 | c.113C>T p.A38V (on ENST00000264773; = p.A250V on NM_021614.4) | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1364442836, COSV53283911; called by muse, mutect2, varscan2
- KCNT2 | c.1139C>G p.A380G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); catalogued as COSV54065901; called by muse, mutect2, varscan2
- KCTD8 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV63585787; called by muse, mutect2, varscan2
- KDM5A | c.3597del p.G1200Dfs*9 | Frame Shift Del (DEL) | VAF 41/100 reads (41%) | catalogued as rs771545848; called by mutect2, varscan2
- KIAA1143 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs144499231; called by muse, mutect2, varscan2
- KIAA1549 | c.2665G>A p.G889S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773756125, COSV54306766, COSV99651769; called by muse, mutect2, varscan2
- KIF19 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs773986695, COSV63428890, COSV63428927; called by muse, mutect2, varscan2
- KIF5A | c.1487T>C p.V496A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as COSV54051987; called by muse, mutect2, varscan2
- KIF7 | c.3760del p.L1254Sfs*22 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs747131428; called by mutect2, pindel, varscan2
- KIFAP3 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs200643889, COSV63031245, COSV63035380; called by muse, mutect2, varscan2
- KIR3DL2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 128/392 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs766298430, COSV54389325; called by muse, varscan2
- KL | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV66307991; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 40/180 reads (22%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHDC7B | c.1490G>A p.R497H (on ENST00000395676; = p.R1138H on NM_138433.5) | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752754069, COSV67464253; called by muse, mutect2, varscan2
- KLHL11 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.23); catalogued as rs782206413, COSV59861469; called by muse, mutect2, varscan2
- KLHL21 | c.1652_1654del p.F551del | In Frame Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs1477349346; called by mutect2, pindel, varscan2
- KLHL26 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs949172381, COSV56316419; called by muse, mutect2, varscan2
- KMT2C | c.7828C>T p.R2610* | Nonsense Mutation (SNP) | VAF 42/132 reads (32%) | catalogued as COSV51326592, COSV51523348; called by muse, mutect2, varscan2
- KNDC1 | c.4117C>T p.R1373W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1195513211, COSV58831736; called by muse, mutect2, varscan2
- KRBA2 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.676); catalogued as rs150010343; called by muse, mutect2, varscan2
- KRT28 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); catalogued as rs1011651056, COSV60683770; called by muse, mutect2, varscan2
- KRT6A | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs747979011, COSV58103879; called by muse, mutect2, varscan2
- KRTAP10-4 | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100555445; called by muse, mutect2, varscan2
- KRTAP10-6 | c.538A>G p.S180G | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV100555089; called by muse, mutect2, varscan2
- KRTAP27-1 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67000900, COSV67001054; called by muse, mutect2, varscan2
- KRTAP5-1 | c.154del p.V52Cfs*? | Frame Shift Del (DEL) | VAF 112/429 reads (26%) | catalogued as COSV66299146; called by mutect2, pindel, varscan2
- KTN1 | c.1461+1G>A p.X487_splice | Splice Site (SNP) | VAF 16/32 reads (50%) | catalogued as COSV68022459; called by muse, mutect2, varscan2
- LAMA3 | c.5934G>T p.R1978S (on ENST00000313654 / NM_198129.4; = p.R369S on NM_000227.6) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as COSV52530427; called by muse, mutect2, varscan2
- LARP1 | c.906del p.T303Pfs*23 (on ENST00000518297 / NM_033551.3; = p.T226Pfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 98/334 reads (29%) | catalogued as rs769338468, COSV60425051; called by mutect2, varscan2
- LAYN | c.599G>A p.G200D (on ENST00000375615 / NM_001258390.1; = p.G192D on NM_178834.5) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1463472126, COSV65104472; called by muse, mutect2, varscan2
- LCT | c.5264G>A p.R1755Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs1383720794, COSV51544707; called by muse, mutect2, varscan2
- LCT | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs143420596; called by muse, mutect2, varscan2
- LDLR | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as CM162619, CM973288, COSV52941816; called by muse, mutect2, varscan2
- LGALS9B | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs561766300, COSV60865232; called by mutect2, varscan2
- LGR5 | c.1938del p.F646Lfs*21 | Frame Shift Del (DEL) | VAF 9/89 reads (10%) | catalogued as COSV57010048; called by mutect2, pindel
- LOX | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs566461481, COSV50236931; called by muse, mutect2, varscan2
- LOXL3 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 33/275 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1218437521, COSV51206250; called by muse, mutect2, varscan2
- LRFN3 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.315); catalogued as rs1345568033, COSV55817048; called by muse, mutect2, varscan2
- LRP12 | c.2503G>A p.A835T | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as rs1010338777, COSV52625990, COSV52629044; called by muse, mutect2
- LRPAP1 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.618); catalogued as rs573489074, COSV56345693; called by muse, varscan2
- LRRTM2 | c.1399C>A p.L467I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV51219961; called by muse, mutect2, varscan2
- LTBP2 | c.3922G>A p.A1308T | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as rs371669746; called by muse, mutect2, varscan2
- LUZP2 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1416888159, COSV61196655; called by muse, mutect2, varscan2
- MACF1 | c.15526G>A p.V5176I (on ENST00000372915; = p.V3109I on NM_012090.5) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs760712619, COSV57108360; called by muse, mutect2, varscan2
- MAG | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200718920, COSV62699130; called by muse, mutect2, varscan2
- MAP3K14 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs759696785, COSV60922773; called by muse, mutect2, varscan2
- MAPK1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV53185080; called by muse, mutect2, varscan2
- MAPKAPK5 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.153); catalogued as rs765163892, COSV73436051; called by muse, mutect2, varscan2
- MAST3 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as COSV53217858; called by muse, mutect2, varscan2
- MAST3 | c.1628C>T p.T543M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257364310, COSV53217870; called by muse, mutect2, varscan2
- MAVS | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV63926494; called by muse, mutect2, varscan2
- MCF2L2 | c.316A>G p.R106G | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61049778; called by muse, mutect2, varscan2
- METTL22 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 151/453 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV50837423; called by muse, mutect2, varscan2
- METTL24 | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58821120; called by muse, mutect2, varscan2
- MGA | c.3127C>T p.R1043* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as COSV54949521; called by muse, mutect2, varscan2
- MGA | c.6143C>T p.S2048F (on ENST00000219905 / NM_001164273.1; = p.S1839F on NM_001080541.2) | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as COSV54949533, COSV54950693; called by muse, mutect2, varscan2
- MICU3 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as COSV58844934; called by muse, varscan2
- MINAR1 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs140205068; called by muse, varscan2
- MLLT6 | c.1693G>A p.G565R | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs982994615; called by muse, mutect2, varscan2
- MMP21 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV64288767; called by muse, mutect2, varscan2
- MMS22L | c.2529G>T p.E843D | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51517085; called by muse, mutect2, varscan2
- MOV10 | c.2114G>A p.R705Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765934294, COSV53516791; called by muse, mutect2, varscan2
- MOV10L1 | c.2950C>T p.R984W | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs377228035; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1337C>A p.P446H | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV56617210; called by muse, mutect2, varscan2
- MPL | c.1697G>A p.S566N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV65244174; called by muse, mutect2, varscan2
- MRC2 | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1428228031, COSV100316764, COSV57639359; called by muse, mutect2, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | catalogued as rs34028511; called by mutect2, pindel
- MSL2 | c.1427G>A p.C476Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV53860099; called by muse, mutect2, varscan2
- MSX1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342784720, COSV66947006; called by muse, mutect2, varscan2
- MTCL1 | c.3884G>A p.R1295H (on ENST00000306329 / NM_001378206.1; = p.R976H on NM_015210.4) | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1054270301, COSV60403626, COSV60409473, COSV60413105; called by muse, mutect2, varscan2
- MTMR3 | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs755680177, COSV60302086; called by muse, mutect2, varscan2
- MUC16 | c.32368T>A p.S10790T | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.047); catalogued as COSV67447706; called by muse, mutect2, varscan2
- MUC16 | c.28289dup p.N9430Kfs*27 | Frame Shift Ins (INS) | VAF 48/139 reads (35%) | catalogued as rs774904775; called by mutect2, varscan2
- MUC20 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.162); catalogued as COSV57847895; called by muse, mutect2, varscan2
- MXRA8 | c.901del p.R301Gfs*107 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs764857791; called by mutect2, pindel, varscan2
- MYH10 | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV52595655; called by muse, mutect2, varscan2
- MYH4 | c.3472G>A p.G1158S | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs764056557, COSV55113103; called by muse, mutect2, varscan2
- MYO15A | c.9965T>C p.L3322P | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52752478; called by muse, mutect2, varscan2
- MYO18B | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs566950878, COSV59126592; called by muse, mutect2, varscan2
- MYO7A | c.2920C>T p.R974W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs782582076, COSV68683616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO9B | c.4738C>T p.R1580C | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs767106410, COSV68277276; called by muse, mutect2, varscan2
- MYOD1 | c.454A>G p.N152D | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV51452730; called by muse, mutect2, varscan2
- MYOF | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.111); catalogued as COSV100825364, COSV63700723; called by muse, mutect2, varscan2
- NABP2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs771670379, COSV57211992; called by muse, mutect2, varscan2
- NAIF1 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV66089924; called by muse, mutect2, varscan2
- NALCN | c.4624G>A p.V1542M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51919470; called by muse, mutect2, varscan2
- NBAS | c.6636C>A p.N2212K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.034); catalogued as rs779958737, COSV55713658; called by muse, mutect2, varscan2
- NBAS | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55713667; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | catalogued as rs763376147; called by mutect2, varscan2
- NBPF1 | c.1379G>T p.R460M | Missense Mutation (SNP) | VAF 32/733 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV55321224, COSV99844906; called by muse, mutect2
- NCAPD3 | c.1330C>A p.L444M | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV73257916; called by muse, mutect2, varscan2
- NCLN | c.1525C>A p.Q509K | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV55741969; called by muse, mutect2, varscan2
- NCOA7 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 53/141 reads (38%) | catalogued as rs777959779, COSV57652818, COSV57654840; called by muse, mutect2, varscan2
- NCOR2 | c.2538del p.A847Rfs*117 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as COSV62300850; called by mutect2, pindel, varscan2
- NDUFA9 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs71579254, COSV56927839; called by muse, mutect2, varscan2
- NEB | c.12062G>A p.G4021D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780030963, COSV50821031; called by muse, mutect2, varscan2
- NEK9 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.381); catalogued as COSV99464515; called by muse, mutect2, varscan2
- NES | c.126del p.L43Sfs*67 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs1437202416; called by mutect2, varscan2
- NFATC1 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as rs753211496, COSV53694701; called by muse, mutect2, varscan2
- NFKBID | c.830G>A p.R277H (on ENST00000396901; = p.R429H on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1278187435, COSV61727815; called by muse, mutect2, varscan2
- NIPA2 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754585304, COSV57405841; called by muse, mutect2, varscan2
- NIPBL | c.2158G>T p.G720W | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV56943595; called by muse, mutect2, varscan2
- NKAIN2 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs768539349, COSV63644826; called by muse, mutect2, varscan2
- NKX2-3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1188641625, COSV60728364, COSV60728994; called by muse, mutect2, varscan2
- NKX3-2 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1288795047, COSV66711506; called by muse, mutect2, varscan2
- NLGN1 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762922847, COSV64324585; called by muse, mutect2, varscan2
- NOBOX | c.487dup p.R163Pfs*48 | Frame Shift Ins (INS) | VAF 26/40 reads (65%) | catalogued as rs754069719; called by mutect2, varscan2
- NOL8 | c.1823C>A p.P608H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV62634253; called by muse, mutect2, varscan2
- NOP2 | c.712C>T p.R238* (on ENST00000322166 / NM_001258308.2; = p.R234* on NM_006170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV59109586; called by muse, mutect2, varscan2
- NOS1 | c.3866G>A p.R1289Q | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs199524143, COSV57607574; called by muse, mutect2, varscan2
- NOS1 | c.3074A>T p.N1025I | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as COSV57607584; called by muse, mutect2, varscan2
- NOTCH2 | c.3598G>T p.G1200C | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56683059; called by muse, mutect2, varscan2
- NPC1L1 | c.3320T>C p.L1107P | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56922807; called by muse, mutect2, varscan2
- NPC1L1 | c.2357T>C p.L786P | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56922815; called by muse, mutect2, varscan2
- NPSR1 | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.54); catalogued as rs746170243, COSV63103090; called by muse, mutect2, varscan2
- NPTN | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54736848; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | catalogued as rs774343392; called by mutect2, varscan2
- NR2F1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59067639; called by muse, mutect2, varscan2
- NRG1 | c.235T>C p.S79P (on ENST00000523534; = p.S226P on NM_013962.2) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV73057926; called by muse, mutect2, varscan2
- NSD2 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs1278980140, COSV56386979; called by muse, mutect2, varscan2
- NUCB1 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as rs371661389; called by muse, mutect2, varscan2
- NUP133 | c.2660G>A p.R887H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.921); catalogued as rs375446105; called by muse, mutect2, varscan2
- NUP155 | c.484C>T p.R162* (on ENST00000231498 / NM_153485.3; = p.R103* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as rs765177729, COSV51527298; called by muse, mutect2, varscan2
- NUP214 | c.2280G>A p.S760= | Splice Region (SNP) | VAF 21/59 reads (36%) | catalogued as rs373361188; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUTM1 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61546079; called by muse, mutect2, varscan2
- NXPE4 | c.1525A>G p.S509G (on ENST00000375478 / NM_001077639.2; = p.S225G on NM_017678.3) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64943443; called by muse, mutect2, varscan2
- OBSCN | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as rs756875131, COSV52745628; called by muse, mutect2, varscan2
- OBSCN | c.11317G>T p.G3773C | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52745666; called by muse, mutect2, varscan2
- OBSL1 | c.1869G>T p.E623D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV54713516; called by muse, mutect2, varscan2
- OCA2 | c.1841dup p.H615Afs*2 | Frame Shift Ins (INS) | VAF 32/114 reads (28%) | catalogued as rs1322260893; called by mutect2, varscan2
- OLFML3 | c.795del p.Y266Tfs*3 | Frame Shift Del (DEL) | VAF 40/125 reads (32%) | catalogued as rs753594963; called by mutect2, pindel, varscan2
- OPRK1 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55568616; called by muse, mutect2, varscan2
- OR2B6 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55128468; called by muse, mutect2, varscan2
- OR2H2 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as rs759258206, COSV63541036; called by muse, varscan2
- OR51F2 | c.986A>G p.Y329C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100437983, COSV59063842; called by muse, mutect2, varscan2
- OR51I1 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV66507288; called by muse, mutect2, varscan2
- OR5M10 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1226153143, COSV73242257; called by muse, mutect2
- OR8G2P | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs369748247; called by muse, varscan2
- OTOL1 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV60006028, COSV60006472; called by muse, mutect2, varscan2
- OTX2 | c.106del p.R36Gfs*15 (on ENST00000408990 / NM_172337.3; = p.R44Gfs*15 on NM_021728.4) | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as CD124838, COSV100258088; called by mutect2, pindel, varscan2
- OXSM | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55000817; called by muse, mutect2, varscan2
- PAIP2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs925613191, COSV99497386; called by muse, mutect2, varscan2
- PAPLN | c.2908G>A p.A970T (on ENST00000554301; = p.A943T on NM_173462.4) | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.543); catalogued as COSV53713594; called by muse, mutect2, varscan2
- PARD3B | c.2509del p.T837Rfs*13 (on ENST00000406610 / NM_001302769.2; = p.T768Rfs*13 on NM_057177.7) | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs772816756; called by mutect2, pindel, varscan2
- PATL1 | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755793315, COSV55688106; called by muse, mutect2, varscan2
- PAX7 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745583358, COSV64748193, COSV64748751; called by muse, mutect2
- PCDH7 | c.3091G>A p.V1031M | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV62336880; called by muse, mutect2
- PCDH8 | c.2141G>A p.G714D | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.225); catalogued as COSV58811001; called by muse, mutect2, varscan2
- PCDHA12 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.871); catalogued as rs1266651704, COSV56480427; called by muse, mutect2, varscan2
- PCDHA4 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.336); catalogued as COSV63539239; called by muse, mutect2, varscan2
- PCDHA7 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.972); catalogued as rs782425324, COSV65342157, COSV65347667; called by muse, mutect2, varscan2
- PCDHB12 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1170138951, COSV53393512; called by muse, mutect2, varscan2
- PCDHB13 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as rs1554287651, COSV53393516; called by muse, mutect2, varscan2
- PCDHB15 | c.1330G>A p.V444I | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.017); catalogued as COSV50860301; called by muse, mutect2, varscan2
- PCDHB7 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.258); catalogued as rs369077920; called by muse, mutect2, varscan2
- PCDHGA1 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 67/264 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65295131; called by muse, mutect2, varscan2
- PCDHGA6 | c.1664A>G p.Q555R | Missense Mutation (SNP) | VAF 89/363 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV53905395; called by muse, mutect2, varscan2
- PCDHGB5 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.406); catalogued as COSV53905407; called by muse, mutect2, varscan2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | catalogued as rs772305388; called by mutect2, pindel, varscan2
- PCLO | c.15007G>A p.A5003T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV61617899; called by muse, mutect2, varscan2
- PCNX3 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs372609082; called by muse, mutect2, varscan2
- PDCD6IP | c.603A>T p.L201F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.044); catalogued as rs760399252, COSV56241488; called by muse, mutect2, varscan2
- PDE2A | c.1633G>A p.G545S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57802952; called by muse, mutect2, varscan2
- PDGFRA | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57265152; called by muse, mutect2, varscan2
- PDLIM2 | c.167G>A p.S56N (on ENST00000397760; = p.S306N on NM_021630.6) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs773451486, COSV56131725; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs747131399; called by mutect2, varscan2
- PDXDC1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs376738752; called by muse, mutect2, varscan2
- PDZD2 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs749035781, COSV56851838; called by muse, mutect2, varscan2
- PELI3 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 86/264 reads (33%) | catalogued as rs773430349, COSV57856143; called by muse, varscan2
- PELI3 | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs150549632; called by muse, varscan2
- PEX2 | c.542A>G p.Q181R | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV63813163; called by muse, mutect2, varscan2
- PEX3 | c.579-1G>T p.X193_splice | Splice Site (SNP) | VAF 10/21 reads (48%) | catalogued as COSV62568049; called by muse, mutect2, varscan2
- PFKP | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1268502751, COSV66895222; called by muse, mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 40/150 reads (27%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHLDB2 | c.2451del p.V822Lfs*6 (on ENST00000393925 / NM_001134439.2; = p.V779Lfs*6 on NM_145753.2) | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs1193567996, COSV101208463; called by mutect2, pindel, varscan2
- PHRF1 | c.4627_4629del p.E1543del (on ENST00000264555 / NM_001286581.2; = p.E1542del on NM_020901.4) | In Frame Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs758340144; called by pindel, varscan2
- PIP4K2C | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 19/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61605728, COSV61607084; called by muse, mutect2
- PITPNM3 | c.2122G>T p.G708W | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52593223; called by muse, mutect2, varscan2
- PITX1 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV54761590; called by muse, mutect2, varscan2
- PKD1 | c.11209G>T p.G3737W (on ENST00000262304 / NM_001009944.3; = p.G3736W on NM_000296.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD1210739, COSV51911374; called by muse, mutect2, varscan2
- PKD1 | c.8741G>A p.S2914N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as rs774306300, COSV51911380; called by muse, mutect2, varscan2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs1335792632, COSV60133695; called by mutect2, pindel, varscan2
- PLAG1 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs777394883, COSV57609536; called by muse, mutect2, varscan2
- PLCD4 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1450426982, COSV68842142; called by muse, mutect2, varscan2
- PLD4 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs1334077652, COSV66914757, COSV66915138; called by muse, mutect2, varscan2
- PLEKHG1 | c.3056C>T p.A1019V | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1298950718, COSV62045324; called by muse, mutect2, varscan2
- PLEKHG4B | c.3565T>C p.S1189P (on ENST00000283426; = p.S1545P on NM_052909.5) | Missense Mutation (SNP) | VAF 57/173 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV52044128; called by muse, mutect2, varscan2
- PLK3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV64728119; called by muse, mutect2, varscan2
- PLPPR3 | c.1193C>T p.P398L (on ENST00000520876 / NM_001270366.2; = p.P426L on NM_024888.2) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs773585263, COSV62458786; called by muse, mutect2, varscan2
- PLXNA3 | c.2840C>T p.A947V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV63753297; called by muse, mutect2
- PLXNB1 | c.3236C>T p.T1079I | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV56486966; called by muse, mutect2, varscan2
- PMF1 | c.522G>T p.E174D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.339); catalogued as COSV60771084; called by muse, mutect2, varscan2
- PMF1-BGLAP | c.369-4G>A | Splice Region (SNP) | VAF 49/150 reads (33%) | catalogued as COSV60771079; called by muse, mutect2, varscan2
- PNPLA7 | c.432G>A p.R144= | Splice Region (SNP) | VAF 35/90 reads (39%) | catalogued as COSV52994832; called by muse, mutect2, varscan2
- POGZ | c.3257G>A p.R1086Q | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as rs752124802, COSV51850511; called by muse, mutect2, varscan2
- POLD3 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs377052981; called by muse, mutect2, varscan2
- POLE | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1483635586, COSV57674926; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1H | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV60137600; called by muse, mutect2, varscan2
- POMC | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs1247595445, COSV53034413; called by muse, mutect2, varscan2
- POMT1 | c.1118A>G p.N373S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756531223, COSV61225133; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPIL2 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 77/226 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as rs778948703, COSV58604917; called by muse, mutect2, varscan2
- PPOX | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.152); catalogued as rs773171980, COSV57086963; called by muse, mutect2, varscan2
- PPP2R2C | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58670549; called by muse, mutect2, varscan2
- PPP2R2D | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs577541215, COSV70778620; called by muse, mutect2, varscan2
- PPP2R5A | c.*7del | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs540232176; called by mutect2, varscan2
- PPP3R2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs1378306586, COSV100701405, COSV62450758; called by muse, mutect2, varscan2
- PREPL | c.710A>G p.D237G | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV53215222; called by muse, mutect2, varscan2
- PRG4 | c.2366C>A p.P789H | Missense Mutation (SNP) | VAF 159/387 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV63355032; called by muse, mutect2, varscan2
- PRRC2C | c.1388G>A p.R463H (on ENST00000367742; = p.R461H on NM_015172.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1429543851, COSV58901702; called by muse, mutect2, varscan2
- PRSS55 | c.467A>G p.D156G | Missense Mutation (SNP) | VAF 59/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60807797; called by muse, mutect2, varscan2
- PRSS57 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368246461; called by muse, mutect2, varscan2
- PRSS8 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs371799687; called by muse, mutect2, varscan2
- PRSS8 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs745405432, COSV54895306; called by muse, mutect2, varscan2
- PSEN1 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56193153; called by muse, mutect2, varscan2
- PTCH2 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772212841, COSV64709895, COSV64711757; called by muse, mutect2, varscan2
- PTCHD4 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.212); catalogued as rs758042146, COSV59778781; called by muse, mutect2, varscan2
- PTP4A3 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs776517948, COSV61471165; called by muse, mutect2, varscan2
- PTP4A3 | c.476G>A p.R159Q (on ENST00000329397; = p.R134Q on NM_007079.3) | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs754768750, COSV61471065, COSV61471173; called by muse, mutect2, varscan2
- PTPN13 | c.2405T>C p.V802A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57403202; called by muse, mutect2, varscan2
- PTPN13 | c.7447C>A p.L2483I (on ENST00000411767 / NM_080683.3; = p.L2464I on NM_006264.3) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); catalogued as COSV57403210; called by muse, mutect2, varscan2
- PTPN14 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.989); catalogued as COSV65281738; called by muse, mutect2, varscan2
- PTPN5 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV62124921; called by muse, mutect2, varscan2
- PTPRD | c.4841C>G p.T1614S | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV61930516; called by muse, mutect2, varscan2
- PTPRM | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs1332871442, COSV59845848; called by muse, mutect2, varscan2
- PTPRO | c.881C>T p.T294M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs779152143, COSV55504104; called by muse, mutect2, varscan2
- PUS7 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs200210514, COSV62675990; called by muse, mutect2, varscan2
- PVRIG | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1309050825, COSV52780450; called by muse, mutect2, varscan2
- PWWP2B | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1445001493, COSV59449105; called by muse, varscan2
- PXDNL | c.2647G>A p.A883T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.565); catalogued as COSV62479642; called by muse, mutect2, varscan2
- PYROXD2 | c.470A>G p.Q157R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs759706548, COSV65328946; called by muse, mutect2, varscan2
- RAB8B | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100369059; called by muse, mutect2, varscan2
- RAI1 | c.4429C>T p.P1477S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs763769196, COSV55389686; called by muse, mutect2, varscan2
- RAI14 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.575); catalogued as COSV54290069; called by muse, mutect2, varscan2
- RANBP9 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV50580313; called by muse, mutect2, varscan2
- RASSF1 | c.680G>A p.R227H (on ENST00000357043 / NM_170714.2; = p.R223H on NM_007182.5) | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as rs587769866, COSV51700110; called by muse, mutect2, varscan2
- RBM33 | c.3089dup p.L1031Pfs*109 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs766836538; called by mutect2, varscan2
- RBM34 | c.244dup p.T82Nfs*5 | Frame Shift Ins (INS) | VAF 14/78 reads (18%) | catalogued as rs768846936; called by mutect2, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 26/96 reads (27%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RBPMS2 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55603651; called by muse, mutect2, varscan2
- RCSD1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750952554, COSV63257970; called by muse, mutect2, varscan2
- RECQL4 | c.2957A>G p.E986G | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV56739426; called by muse, mutect2, varscan2
- RFC1 | c.2980G>A p.V994I (on ENST00000381897 / NM_001363496.2; = p.V993I on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs963487293, COSV62898497; called by muse, mutect2, varscan2
- RFX3 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 18/65 reads (28%) | catalogued as rs757065522, COSV56508759; called by muse, mutect2, varscan2
- RFXANK | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs780019385, COSV57393150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RGL2 | c.1564C>T p.R522W | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs892207416, COSV65841986; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RIC3 | c.326dup p.L109Ffs*9 | Frame Shift Ins (INS) | VAF 17/70 reads (24%) | catalogued as rs746684945; called by mutect2, varscan2
- RILP | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.842); catalogued as COSV53957562; called by muse, mutect2, varscan2
- RIMS1 | c.54del p.M19Cfs*7 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1378143186; called by pindel, varscan2
- RIMS1 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1260133678, COSV53441288; called by muse, varscan2
- RNASEH2A | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 70/204 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs942243073, COSV55551248; called by muse, varscan2
- RNF157 | c.1985G>T p.S662I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV53942198; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 125/229 reads (55%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF6 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436553487, COSV60417937; called by muse, mutect2, varscan2
- RORC | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59091707; called by muse, mutect2, varscan2
- RPL12 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV55938486; called by muse, mutect2, varscan2
- RPL22 | c.43_44del p.K15Efs*9 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs759765382; called by pindel, varscan2
- RPL3L | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs148367011; called by mutect2, varscan2
- RPTOR | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 140/396 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs748079762, COSV60803862; called by muse, mutect2, varscan2
- RSBN1 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54731195, COSV54736028; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 20/26 reads (77%) | catalogued as rs747510098; called by mutect2, varscan2
- RUNX3 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1487446167, COSV58242731; called by muse, mutect2, varscan2
- RUVBL2 | c.889T>G p.F297V | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55484329; called by muse, mutect2, varscan2
- RYR2 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs758904216, COSV63665056; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- RYR2 | c.9856A>G p.N3286D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV63665062; called by muse, mutect2, varscan2
- RYR3 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370528698; called by muse, mutect2, varscan2
- S100B | c.112A>G p.N38D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV52452705; called by muse, mutect2, varscan2
- SACS | c.9777_9779del p.E3259del | In Frame Del (DEL) | VAF 14/50 reads (28%) | catalogued as rs768958169; called by pindel, varscan2
- SAG | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.013); catalogued as rs775968495, COSV68590375; called by muse, mutect2, varscan2
- SBK1 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777291014, COSV59396098; called by muse, mutect2, varscan2
- SBK1 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59396117; called by muse, mutect2, varscan2
- SCN1A | c.5566A>G p.M1856V (on ENST00000303395 / NM_001202435.3; = p.M1845V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV57661493; called by muse, mutect2, varscan2
- SCN5A | c.5701G>A p.E1901K (on ENST00000333535 / NM_198056.3; = p.E1900K on NM_000335.5) | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473325, CM097691; ClinVar: not provided; called by muse, mutect2, varscan2
- SEC16A | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs779447176, COSV51522035; called by muse, mutect2, varscan2
- SECISBP2 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100368890; called by muse, mutect2, varscan2
- SELENOP | c.377T>C p.L126P | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV62791777; called by muse, varscan2
- SEMA6D | c.2989C>T p.R997C (on ENST00000316364 / NM_153618.2; = p.R935C on NM_020858.2) | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as rs763608914, COSV60373241; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as rs750651342; called by mutect2, varscan2
- SERINC2 | c.584A>C p.E195A (on ENST00000373709 / NM_178865.5; = p.E199A on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV65489444; called by muse, mutect2, varscan2
- SERPINB8 | c.575dup p.T193Dfs*7 | Frame Shift Ins (INS) | VAF 12/45 reads (27%) | catalogued as rs1568275935; called by mutect2, varscan2
- SETBP1 | c.3056G>A p.R1019H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs140544874; called by muse, mutect2, varscan2
- SETBP1 | c.4310A>G p.K1437R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99029963, COSV99951829, COSV99955519; called by muse, mutect2, varscan2
- SFI1 | c.1622_1623del p.R541Nfs*13 (on ENST00000400288 / NM_001007467.3; = p.R510Nfs*13 on NM_014775.4) | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs749968920; called by pindel, varscan2
- SFMBT2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62805927; called by muse, mutect2, varscan2
- SGCD | c.124A>G p.M42V (on ENST00000435422 / NM_001128209.2; = p.M43V on NM_000337.5) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV61904493; called by muse, mutect2, varscan2
- SGO2 | c.1929del p.G644Vfs*18 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | catalogued as rs1260834379; called by mutect2, pindel, varscan2
- SGPP1 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV55974635; called by muse, mutect2, varscan2
- SGSM1 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV68508945; called by muse, mutect2, varscan2
- SH3GL1 | c.729-1G>T p.X243_splice | Splice Site (SNP) | VAF 47/113 reads (42%) | catalogued as COSV53656076; called by muse, mutect2, varscan2
- SH3PXD2A | c.2927C>T p.A976V (on ENST00000369774 / NM_001365079.1; = p.A948V on NM_014631.2) | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.986); catalogued as rs373805914; called by muse, mutect2, varscan2
- SHROOM1 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60580609; called by muse, mutect2, varscan2
- SIPA1L2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs369266455; called by muse, mutect2, varscan2
- SLC12A7 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV53754838; called by muse, mutect2
- SLC18A2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV53688687; called by muse, mutect2
- SLC27A2 | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs769777777, COSV51057641; called by muse, mutect2, varscan2
- SLC27A4 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs1260284783, COSV55958899; called by muse, mutect2, varscan2
- SLC35B1 | c.890C>T p.T297M (on ENST00000649906; = p.T260M on NM_005827.4) | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.475); catalogued as rs142991261; called by muse, mutect2, varscan2
- SLC35F4 | c.210A>G p.L70= | Splice Region (SNP) | VAF 9/18 reads (50%) | catalogued as COSV60262925; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 42/122 reads (34%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC36A1 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.407); catalogued as rs943359511, COSV54652291; called by muse, mutect2, varscan2
- SLC38A2 | c.632T>C p.L211P | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56744180; called by muse, mutect2, varscan2
- SLC39A12 | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV66195555; called by muse, mutect2, varscan2
- SLC46A2 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV65289616; called by muse, mutect2, varscan2
- SLC7A13 | c.488G>A p.S163N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.773); catalogued as COSV52532746; called by muse, mutect2, varscan2
- SLC7A14 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV51578277; called by muse, mutect2, varscan2
- SLCO4C1 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV60513065; called by muse, mutect2, varscan2
- SLITRK5 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV61520886, COSV61521204; called by muse, mutect2, varscan2
- SLTM | c.1539del p.E514Kfs*8 | Frame Shift Del (DEL) | VAF 13/48 reads (27%) | catalogued as rs1319405514; called by mutect2, varscan2
- SMARCA4 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 19/231 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.069); catalogued as rs755069412, COSV60787597; ClinVar: uncertain significance; called by muse, mutect2
- SMARCAL1 | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs189863563, COSV61920034; called by muse, mutect2, varscan2
- SMARCB1 | c.214del p.T72Qfs*13 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | catalogued as COSV99574633; called by mutect2, pindel, varscan2
- SMPD2 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs746059256, COSV57804362; called by muse, mutect2, varscan2
- SNAPC2 | c.669del p.E224Sfs*33 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | catalogued as rs1568289480; called by mutect2, pindel, varscan2
- SNX18 | c.1120G>T p.V374F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV57987807, COSV57988379; called by muse, mutect2, varscan2
- SNX31 | c.1296del p.F432Lfs*4 | Frame Shift Del (DEL) | VAF 8/71 reads (11%) | catalogued as rs761306337, COSV100310326; called by mutect2, pindel, varscan2
- SORCS1 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146666715, COSV53853541; called by muse, mutect2, varscan2
- SORL1 | c.4741del p.M1581Cfs*34 | Frame Shift Del (DEL) | VAF 36/114 reads (32%) | catalogued as rs1278336874; called by mutect2, pindel, varscan2
- SOS1 | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 86/218 reads (39%) | catalogued as COSV67674007; called by muse, mutect2, varscan2
- SOX30 | c.1789C>A p.L597I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV53936249; called by muse, mutect2, varscan2
- SP100 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs1238770937, COSV50974796; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs746109620; called by mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 60/146 reads (41%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPHKAP | c.1775C>A p.A592E | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV60869857; called by muse, mutect2, varscan2
- SPOUT1 | c.102del p.K34Nfs*7 | Frame Shift Del (DEL) | VAF 63/166 reads (38%) | catalogued as rs749421754; ClinVar: uncertain significance; called by mutect2, varscan2
- SPTBN2 | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113974204, COSV59447719; called by muse, mutect2, varscan2
- SRCAP | c.3047G>A p.R1016Q | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs759674329, COSV52668007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRP68 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.32); catalogued as rs781574834, COSV57161626; called by muse, mutect2, varscan2
- SRPK2 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV61959498; called by muse, mutect2, varscan2
- SSTR3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs201547867, COSV60728693; called by muse, mutect2, varscan2
- ST18 | c.1215G>A p.M405I | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1477974612, COSV52485627; called by muse, mutect2, varscan2
- STAM | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66324956; called by muse, mutect2, varscan2
- STAT5B | c.232del p.E78Kfs*6 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | catalogued as COSV53184951; called by mutect2, pindel, varscan2
- STC2 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs925905197, COSV54177982; called by muse, mutect2, varscan2
- STRADB | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs771728565, COSV52042761, COSV52042905; called by muse, varscan2
- STRAP | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs947112729, COSV50308235; called by muse, mutect2, varscan2
- STRIP1 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs762351041, COSV63929742; called by muse, mutect2, varscan2
- STX4 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs1488866019, COSV58267914; called by muse, mutect2, varscan2
- SUCLG2 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56202386; called by muse, mutect2, varscan2
- SV2C | c.139A>T p.S47C | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.401); catalogued as COSV59214869; called by muse, mutect2, varscan2
- SVEP1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57030078; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | catalogued as rs570102997; called by mutect2, varscan2
- SYNE1 | c.22715C>T p.A7572V (on ENST00000367255 / NM_182961.4; = p.A7501V on NM_033071.3) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as COSV54916598; called by muse, mutect2
- TADA3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as rs367779444; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D9 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764603749, COSV71306969; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
645 further variants in this file (295 protein-altering or splice-affecting, 319 silent, 31 other) are not listed here.
